Somatic mutation profile of tumor specimen 0DPZTM from CCDI case PBCEFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,635 days).
Specimen 0DPZTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7be4c3b7-a67b-4e92-8fe5-9e982f35e422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c4e0d33-ef95-4e1f-a8c7-429bd909dec1

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 90/382 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 356/547 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DAXX | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 63/228 reads (28%) | catalogued as COSV56473040; called by muse, mutect2, varscan2
- DYRK1B | c.1617G>A p.G539= | Silent (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- HSPG2 | c.7407G>A p.T2469= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as rs200462415, COSV65972416; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTT | c.8205C>T p.D2735= | Silent (SNP) | VAF 44/293 reads (15%) | catalogued as rs754534599, COSV61860849; called by muse, mutect2, varscan2
- PEX11G | c.654C>T p.G218= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- ROBO1 | c.1305A>G p.G435= | Silent (SNP) | VAF 92/652 reads (14%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13812G>A | Intron (SNP) | VAF 61/228 reads (27%) | catalogued as rs904381507; called by muse, varscan2
- ATP8B1 | c.2098-74G>C | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as rs998493697; called by muse, varscan2
